Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A180, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A180-06A (Metastatic).

12/19/10 *fw*

1CB-0-3

Melanoma, NOS 8720/3
Site Code: Shoulder, NOS C44.6
Male

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma left posterior shoulder. Tumour (L) posterior shoulder.

MACROSCOPIC DESCRIPTION

SPECIMEN UNLABELLED AS TO NATURE OR SITE. An unorientated skin ellipse, 65 x 28 x 18mm, with a subcuticular brown circumscribed lesion, 18 x 17 x 12mm. Within the lesion, there is a central cavity measuring 5mm in maximum dimension. Representative sections embedded in A-D. Margins inked blue.

MICROSCOPIC REPORT

Sections show a deposit of malignant melanoma within the subcutis. Non-refractile brown cytoplasmic pigment is noted within occasional tumour cells and scattered histiocytes. There is no involvement of the overlying epidermis. The lines of resection appear clear of the lesion; the closest margin (deep) is clear of tumour by 0.5mm.

SUMMARY

Left posterior shoulder: Malignant melanoma,

REPORTED BY:

Source: NCI Genomic Data Commons file b0aa84ff-0d6f-4d66-9ce5-7665eb5a6c32 (TCGA-EE-A180.5E0C8993-FA2B-4856-A850-7764D7F132D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).